TCGA case TCGA-K6-A3WQ — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: ABS - Lahey Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d6303a05-f705-4413-8860-506a105d5b08

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 427 days (1.2 years).

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 60.5 years (22,092 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; FIGO stage: Stage IVB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 427 days (1.2 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 1; Lymph nodes tested: 2.
   Pathology details: Consistent pathology review: No; Percent tumor invasion: 95.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 75 days; Days to treatment end: 167 days.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 246 days; Days to treatment end: 258 days; Treatment dose: 2,100 cGy; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Days to treatment start: 351 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Days to treatment start: 384 days (1.1 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS), site: Uterus, NOS. Age at diagnosis: 61.4 years (22,443 days); Days to diagnosis: 351 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 61.5 years (22,474 days); Days to diagnosis: 382 days (1.0 years); Prior treatment: Yes.

Follow-up (6 entries)
- Days to follow up: 204 days; Disease response: Tumor Free.
- Day 351 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Uterus, NOS; Days to recurrence: 351 days.
- Day 382 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Peritoneum, NOS; Days to recurrence: 382 days (1.0 years).
- Days to follow up: 400 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 427 days (1.2 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 99 kg; Height: 171 cm; BMI: 33.9.
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 1; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-K6-A3WQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 440 mg.
  Slide TCGA-K6-A3WQ-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 3; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 20.
- Sample TCGA-K6-A3WQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-K6-A3WQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form 1: Lost to follow-up: No; Hypertension diagnosis: No; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 1; History colorectal cancer: No; Tumor status: With tumor.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 4: Pharmaceutical therapy drug name: Doxil; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 427 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 427 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 351 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-K6-A3WQ-01A-11D-A227-01): tumor purity 0.78, ploidy 3.38, whole-genome doublings 1.
